Gene-level copy-number profile of tumor specimen C3L-00001-02 from CPTAC case C3L-00001, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 61.5 years (22,455 days).
Specimen C3L-00001-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c32c3284-598d-4425-8ee3-48194f393359.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00001-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/216d54b3-4bab-438f-a63e-306c875e0d78

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 152; copy number 2: 18,396; copy number 3: 24,733; copy number 4: 10,678; copy number 5: 2,805; copy number 6: 673; copy number 7: 567; copy number 8: 145; copy number 9: 40; copy number 10: 126; copy number 23: 2; copy number 28: 7; copy number 33: 11.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:121,325,367–121,396,364, 2 genes: WNT16, FAM3C.
- chr8:7,955,014–8,008,755, 5 genes: FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C.
- chr8:8,027,077–8,040,953, 2 genes: FAM90A12P, OR7E96P.
- chr8:8,095,946–8,096,726, 1 gene: RPS3AP31.
- chr9:60,914,407–62,711,398, 47 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7.
- chr13:101,778,884–102,017,069, 5 genes (within-gene range 0–3): RNU1-24P, HMGB3P7, MIR2681, LIPT1P1, RNY1P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 898 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–784,729, 29 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2.
- chr7:44,217,150–48,108,736, 74 genes, copy number 7 (broad region; genes not listed).
- chr7:54,185,071–55,572,988, 20 genes, copy number 23–33: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.
- chr8:93,213,302–93,700,433, 1 gene, copy number 8 (within-gene range 4–8): LINC00535.
- chr8:93,259,667–93,441,384, 2 genes, copy number 8 (within-gene range 4–8): AC016885.2, RNA5SP274.
- chr8:97,358,265–105,804,539, 175 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:107,857,589–109,334,121, 17 genes, copy number 8: AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1.
- chr12:68,746,125–69,959,097, 32 genes, copy number 9 (within-gene range 6–9): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr14:32,879,246–32,882,830, 1 gene, copy number 8: AL049781.1.
- chr16:90,173,217–90,222,851, 1 gene, copy number 8 (within-gene range 3–8): LINC02193.
- chr21:14,371,115–33,588,706, 320 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr21:34,668,994–41,409,393, 131 genes, copy number 7 (broad region; genes not listed).
- chr21:44,300,051–46,228,824, 95 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
